Gene-level copy-number profile of tumor specimen ALCH-B4QA-TTP1-A from ALCHEMIST case ALCH-B4QA, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 62.9 years (22,982 days).
Specimen ALCH-B4QA-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ec726726-bc58-4f8c-bd8a-67b02cf3d92f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B4QA-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,233 have no estimate.
https://portal.gdc.cancer.gov/files/7e85cc36-5847-43b2-a0bc-38062b129503

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 34; copy number 1: 687; copy number 2: 52,113; copy number 3: 5,447; copy number 4: 79; copy number 5: 18; copy number 6: 5; copy number 7: 3; copy number 13: 2; copy number 14: 1; copy number 27: 1.

Homozygous deletions (total copy number 0; autosomes only): 34 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:4,654,609–4,792,534, 2 genes: AJAP1, Z98886.1.
- chr2:47,035,279–47,040,524, 1 gene (within-gene range 0–2): AC093732.1.
- chr4:49,523,648–49,523,857, 1 gene: AC119751.2.
- chr5:177,086,905–177,098,144, 1 gene: FGFR4.
- chr7:56,805,336–56,808,148, 1 gene: CICP28.
- chr7:128,912,732–128,950,038, 2 genes: AC025594.1, IRF5.
- chr8:22,114,419–22,141,951, 2 genes: HR, REEP4.
- chr9:123,356,170–123,380,324, 1 gene (within-gene range 0–2): CRB2.
- chr9:137,299,631–137,302,271, 1 gene: NRARP.
- chr10:116,749,905–116,751,261, 1 gene: RPL5P27.
- chr15:41,828,092–41,894,053, 6 genes (within-gene range 0–1): JMJD7, JMJD7-PLA2G4B, PLA2G4B, SPTBN5, RNA5SP393, MIR4310.
- chr15:77,568,970–77,820,900, 6 genes: AC046168.2, LINGO1, LINGO1-AS1, LINGO1-AS2, AC105133.2, AC105133.1.
- chr17:142,789–181,650, 1 gene: DOC2B.
- chr17:2,712,309–2,723,947, 2 genes: AC005696.1, AC005696.4.
- chr17:38,671,703–38,674,957, 1 gene: EPOP.
- chr20:50,614,636–50,621,077, 2 genes (within-gene range 0–2): MIR1302-5, RPL36P2.
- chr21:43,358,147–43,427,131, 3 genes: LINC01679, AP001046.1, SIK1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 30 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:242,088,633–242,175,634, 4 genes, copy number 6: LINC01881, CICP10, SEPTIN14P2, RPL23AP88.
- chr7:158,730,995–158,830,253, 1 gene, copy number 5: ESYT2.
- chr9:136,744,017–136,748,525, 2 genes, copy number 7 (within-gene range 2–7): LCN6, MIR6722.
- chr9:136,779,939–136,810,042, 5 genes, copy number 5 (within-gene range 3–5): ATP6V1G1P3, TMEM141, AL355987.3, CCDC183, AL355987.4.
- chr9:136,803,927–136,808,848, 1 gene, copy number 5 (within-gene range 3–5): CCDC183-AS1.
- chr13:114,234,887–114,337,626, 7 genes, copy number 5: CDC16, MIR548AR, MIR4502, UPF3A, CLCP2, CHAMP1, LINC01054.
- chr17:39,757,718–39,877,896, 4 genes, copy number 5: IKZF3, KRT8P34, AC090844.1, ZPBP2.
- chr19:7,037,748–7,058,640, 3 genes, copy number 6–13: MBD3L4, MBD3L2, MBD3L3.
- chr21:43,446,601–43,479,534, 3 genes, copy number 7–27: LINC00319, LINC00313, AP001048.1.

Autosomal genes at a single copy (total copy number 1): 687. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
